MMRF case MMRF_1499 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3c59ccac-7330-4034-a7f9-58984676bc31

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.6 years (25,057 days); ISS stage: II; Days to last known disease status: 1,339 days (3.7 years); Days to last follow up: 1,339 days (3.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 363 days.
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 507 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 25 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 56 days; Days to treatment end: 363 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 624 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 364 days; Days to treatment end: 447 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 448 days (1.2 years); Days to treatment end: 1,232 days (3.4 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 516 days (1.4 years); Days to treatment end: 1,232 days (3.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 624 days (1.7 years); Days to treatment end: 1,232 days (3.4 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,254 days (3.4 years); Days to treatment end: 1,308 days (3.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,309 days (3.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,339.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 2.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.971 mg/dL; Immunoglobulin G 36.4 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.35 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 328 ×10⁹/L; Creatinine 78 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.5 mmol/L; Albumin 32 g/L; Total Protein 8.7 g/dL; Glucose 4.6 mmol/L; C-Reactive Protein 1.95 mg/dL.
- Day 84 (ECOG 1): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.098 mg/dL; Immunoglobulin G 8.08 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 95 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 35.1 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 168 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.793 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 4.89 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 81 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.25 mmol/L; Albumin 32 g/L; Total Protein 6.3 g/dL; Glucose 5.6 mmol/L.
- Day 278 (ECOG 1): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.739 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 3.45 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 90 µmol/L; Blood Urea Nitrogen 6 mmol/L; Calcium 2.32 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 7.9 mmol/L.
- Day 364 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.118 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.044 mg/dL; Immunoglobulin G 3.47 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 85 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 9.5 mmol/L.
- Day 448 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.106 mg/dL; Immunoglobulin G 3.23 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 4.8 mmol/L.
- Day 532 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.028 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.032 mg/dL; Immunoglobulin G 3.18 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 6 mmol/L; Calcium 2.17 mmol/L; Albumin 36.6 g/L; Total Protein 6.1 g/dL; Glucose 6.2 mmol/L.
- Day 623 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.756 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.329 mg/dL; Immunoglobulin G 3.23 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 335 µmol/L; Blood Urea Nitrogen 7.7 mmol/L; Calcium 2.58 mmol/L; Albumin 36.2 g/L; Total Protein 6.1 g/dL; Glucose 4.8 mmol/L.
- Day 700 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.215 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.045 mg/dL; Immunoglobulin G 3.52 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 173 µmol/L; Blood Urea Nitrogen 11.3 mmol/L; Calcium 2.41 mmol/L; Albumin 33 g/L; Total Protein 6.2 g/dL; Glucose 5.4 mmol/L.
- Day 798 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.157 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.105 mg/dL; Immunoglobulin G 3.55 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 10.2 mmol/L; Calcium 2.43 mmol/L; Albumin 40.6 g/L; Total Protein 6.2 g/dL; Glucose 5.8 mmol/L.
- Day 896 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.766 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.593 mg/dL; Immunoglobulin G 3.72 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 151 µmol/L; Blood Urea Nitrogen 8.7 mmol/L; Calcium 2.31 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.9 mmol/L.
- Day 980 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.854 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.239 mg/dL; Immunoglobulin G 4.34 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 155 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.43 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 6.5 mmol/L.
- Day 1,064 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.239 mg/dL; Immunoglobulin G 4.74 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 13 mmol/L; Calcium 2.3 mmol/L; Albumin 39.7 g/L; Total Protein 6.2 g/dL; Glucose 5.5 mmol/L.
- Day 1,169 (ECOG 1): M Protein 5.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.478 mg/dL; Immunoglobulin G 7.98 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 158 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.5 mmol/L; Albumin 40.3 g/L; Total Protein 7.1 g/dL; Glucose 7.4 mmol/L.
- Day 1,232 (ECOG 1): M Protein 5.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.193 mg/dL; Immunoglobulin G 9.77 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 5.3 mmol/L; Calcium 2.22 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 7.2 mmol/L.
- Day 1,330 (ECOG 1): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.138 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 4.28 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 2 mmol/L; Calcium 2.31 mmol/L; Albumin 30.2 g/L; Total Protein 6.1 g/dL; Glucose 5 mmol/L.

Other clinical attributes
- Day 0: Weight: 73 kg; Height: 163 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1499_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1499_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
